Somatic mutation profile of tumor specimen MBCProject_1323_T2_WES (aliquot MBCProject_1323_T2_WES_1) from CMI case MBCProject_1323, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.1 years (14,648 days).
Specimen MBCProject_1323_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38c08f40-1727-43ca-8b39-6f704b210252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1323_SALIVA (Saliva), aliquot MBCProject_1323_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336b56d4-6da5-4dae-9fce-7173093d4b07

The open-access MAF lists 33 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf20 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs762741326, COSV53787970; called by muse, mutect2, varscan2
- CCDC183 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as rs760365822, COSV62013103; called by muse, mutect2, varscan2
- ELOVL6 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1437385411; called by muse, mutect2, varscan2
- HERC2 | c.8305C>T p.R2769C | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs141210218; called by muse, mutect2, varscan2
- IARS1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs760241440, COSV65114609; called by muse, mutect2, varscan2
- INSR | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as rs202160383, COSV57164367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K1 | c.2605A>T p.I869F | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV68128172; called by muse, mutect2, varscan2
- MRGPRX2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs954562936; called by muse, mutect2, varscan2
- PABPC4 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747916449, COSV65723980; called by muse, mutect2, varscan2
- SVIL | c.2429C>G p.S810C (on ENST00000355867 / NM_021738.3; = p.S384C on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV63439786; called by muse, mutect2, varscan2
- TBK1 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as COSV59153051, COSV59155212; called by muse, mutect2, varscan2
- THBS2 | c.1563C>A p.C521* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100827814, COSV99071395; called by muse, mutect2
- AACS | c.293G>C p.R98P | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARID1A | c.3627_3634del p.G1210Afs*7 | Frame Shift Del (DEL) | VAF 16/179 reads (9%) | called by mutect2, pindel
- C10orf90 | c.1962-1G>T p.X654_splice | Splice Site (SNP) | VAF 28/272 reads (10%) | called by muse, mutect2
- CSPP1 | c.3073A>G p.R1025G (on ENST00000676605; = p.R984G on NM_024790.6) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- GATA3 | c.1291_1295del p.G431Tfs*74 | Frame Shift Del (DEL) | VAF 51/194 reads (26%) | called by mutect2, pindel, varscan2
- LANCL3 | c.190G>T p.G64W | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53RK | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 63/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM25 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- CARMIL1 | c.3183G>A p.K1061= | Silent (SNP) | VAF 54/269 reads (20%) | called by muse, mutect2, varscan2
- CCDC178 | c.1431C>T p.Y477= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs200500512; called by muse, mutect2, varscan2
- GDPD4 | c.1119C>T p.Y373= | Silent (SNP) | VAF 50/191 reads (26%) | catalogued as rs139949435; called by muse, mutect2, varscan2
- IL12B | c.117G>A p.P39= | Silent (SNP) | VAF 54/388 reads (14%) | catalogued as COSV51456137; called by muse, mutect2, varscan2
- MYO7A | c.4260C>T p.R1420= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs757844017; called by muse, mutect2, varscan2
- NEU4 | c.1113G>A p.P371= (on ENST00000391969 / NM_001167602.3; = p.P383= on NM_080741.4) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs570038056, COSV100371752; called by muse, mutect2, varscan2
- NOS1 | c.3420C>T p.Y1140= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as rs747681671, COSV100500510; ClinVar: likely benign; called by muse, mutect2, varscan2
- TLR7 | c.3036C>A p.V1012= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- TNXB | c.876T>C p.N292= | Silent (SNP) | VAF 34/153 reads (22%) | called by muse, mutect2, varscan2
- WDR97 | c.4488G>A p.A1496= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- AC009533.1 | n.432G>A | RNA (SNP) | VAF 20/38 reads (53%) | called by mutect2, varscan2
- ANXA8L1 | c.-30C>T | 5'UTR (SNP) | VAF 28/161 reads (17%) | catalogued as rs1325390566; called by muse, mutect2, varscan2
- MBP | c.682-116C>T | Intron (SNP) | VAF 48/189 reads (25%) | called by muse, mutect2, varscan2
